Surgical pathology report (de-identified scan), TCGA case TCGA-98-8021, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-8021-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

Patient Name	MR#	Observation Date	Last Edited Date
--------------	-----	------------------	------------------

[REDACTED]

SURGICAL PATHOLOGY CASE: [REDACTED] Received Date: [REDACTED]

Diagnosis

- A. Lymph node, level IV, excision:
- One lymph node negative for malignancy (0/1).
- B. Lymph node, level II, excision:
- One lymph node negative for malignancy (0/1).
- C. Lymph node, level X, excision:
- One lymph node negative for malignancy (0/1).
- D. Lymph node, level VII, excision:
- One lymph node negative for malignancy (0/1).
- E. Lung, right upper lobe, apical segment, resection:
- Hyalinized plaque.
- No tumor seen.
- F. Lymph node, level VII, second, excision:
- One lymph node negative for malignancy (0/1).
- G. Lymph node, level VII, third, excision:
- One lymph node negative for malignancy (0/1).
- H. Lymph node, level VIII, excision:
- One lymph node negative for malignancy (0/1).
- I. Lymph node, level IX, excision:
- One lymph node negative for malignancy (0/1).
- J. Lymph node, level X, second:
- One lymph node negative for malignancy (0/1).
- K. "Lymph node", level VIII, second:
- Benign fibrovascular tissue.
- No lymphoid tissue identified.
- L. Lung, right upper lobe, wedge resection:
- Invasive squamous cell carcinoma, moderately differentiated, 1.8 cm in maximum gross dimension.
- Pleura and surgical resection margins negative for malignancy.
- Stage: pT1a N0.
- M. Lung, right upper lobe, "rest of apical segment", excision:
- Congestion.
- No tumor seen.
- N. Lymph node, level X, excision:
- One lymph node negative for malignancy (0/1).

[REDACTED] Electronically signed by) Verified: [REDACTED]

[page 2 of 5]
Clinical Information

The patient is a [REDACTED] year-old female with no further history provided.

Frozen Section Diagnosis

A1: Lymph node, #4, excision:

- Negative for tumor.

B1: Lymph node, #2, excision:

- Negative for tumor.

C1: Lymph node, #10, excision:

- Negative for tumor.

D1: Lymph node, #7, excision:

- Negative for tumor.

E1-E3: Lung, right upper lobe, apical segment, resection:

- Hyalinized plaque.

- No carcinoma seen in frozen section.

F1: Lymph node, #7, second, excision:

- Negative for tumor.

H1: Lymph node, #8, excision:

- Negative for tumor.

J1: Lymph node, second #10, excision:

- Negative for tumor.

L1: Lung, right upper lobe, wedge resection:

- Squamous cell carcinoma.

Gross Description

The specimen is received in fourteen containers, each labeled with the patient's name and medical record number.

Part A is received fresh for frozen section, labeled with the patient's name, medical record number and designated "level IV lymph node." The specimen consists of a fragment of yellow soft tissue which measures 1 x 0.8 x 0.2 cm. The specimen was entirely submitted for frozen section and is now resubmitted in its entirety for permanent section.

Part B is received fresh for frozen section, labeled with the patient's name, medical record number and designated "level II lymph node." The specimen consists of a fragment of yellow soft tissue which measures 1.7 x 0.9 x 0.6 cm. The specimen was entirely submitted for frozen section and is now resubmitted in its entirety for permanent section.

Part C is received fresh for frozen section, labeled with the patient's name, medical record number and designated "level X lymph node." The specimen consists of a single fragment of yellow soft tissue which measures 1.2 x 0.8 x 0.4 cm. The specimen was entirely submitted for frozen section and is now resubmitted in its entirety for permanent section.

Part D is received fresh for frozen section, labeled with the patient's name, medical record number and designated "level VII lymph node." The specimen consists of a single fragment of yellow soft tissue which measures 0.4 x 0.3 x 0.2 cm. The specimen was entirely submitted for frozen section and is now resubmitted in its entirety for permanent section wrapped in tissue paper

Part E specimen was previous received fresh for frozen, now in formalin, further designated "#5 - right upper lobe apical segment". Received is a a single wedge of lung measuring 9.0 x 4.0 x 3.0 cm. The pleural surface is tan-pink and remarkable

[page 3 of 5]
for a black-tan-white plaque measuring 2.7 x 2.5 x 0.3 cm. A portion of the plaque was previously submitted for frozen and resubmitted for permanent in cassettes E1-E3. The staple resection margin nearest the plaque is shaved and submitted in cassette E4. Serial sectioning through the remainder of the lung reveals spongy, tan-brown parenchyma with no other gross lesions identified. Representative sections are submitted as per block summary.

Part F is received fresh for frozen section, labeled with the patient's name, medical record number and designated "second level VII lymph node." The specimen consists of multiple fragments of yellow soft tissue which measures 0.6 x 0.3 x 0.2 cm in aggregate. The specimen was entirely submitted for frozen section and is now resubmitted in its entirety for permanent section wrapped in tissue paper.

Part G is received in a container, labeled with the patient's name, medical record number and designated "third level VII lymph node." The specimen consists of multiple fragments of brown soft tissue which measure 2 x 1.9 x 1.1 cm in aggregate. The specimen was submitted in its entirety for permanent section wrapped in tissue paper.

Part H is received fresh for frozen section, labeled with the patient's name, medical record number and designated "level VIII lymph node." The specimen consists of a single fragment of brown soft tissue which measures 0.3 x 0.3 x 0.2 cm in aggregate. The specimen was submitted in its entirety for frozen section and is now resubmitted in its entirety for permanent section wrapped in tissue paper.

Part I is received in a container, labeled with the patient's name, medical record number and designated "level IX lymph node." The specimen consists of a single fragment of brown soft tissue which measures 0.5 x 0.3 x 0.2 cm. The specimen was submitted in its entirety wrapped in tissue paper.

Part J is received fresh for frozen section, labeled with the patient's name, medical record number and designated "second level X lymph node." The specimen consists of a single fragment of yellow soft tissue which measures 0.9 x 0.4 x 0.2 cm in aggregate. The specimen was submitted in its entirety for frozen section and is now resubmitted in its entirety for permanent section.

Part K is received in a container labeled with the patient's name, medical record number and designated "second level VIII lymph node." The specimen consists of two fragments of tan soft tissue which measures 0.8 x 0.6 x 0.3 cm in aggregate. The specimen was submitted in its entirety wrapped in tissue paper.

Part L specimen was previously received fresh for frozen, now in formalin, and further designated "#12 - right upper lobe wedge". Received is a single wedge of lung measuring 6.0 x 3.0 x 2.0 cm. The pleural surface is tan, anthracotic, and grossly unremarkable. The external surface will be inked black and the staple resection margin shaved and submitted in cassette L2. The specimen is serially sectioned and reveals a 1.8 x 1.0 cm well circumscribed tan-yellow lesion located 1.4 cm from the stapled resection margin. A portion of this lesion is submitted for frozen and resubmitted for permanent in cassette L1. The surrounding lung tissue is spongy, tan-brown and grossly unremarkable. Representative sections are submitted as per block summary.

Part M specimen is received in formalin and further designated "#13 - the rest of a apical segment of right upper lobe". Received is a wedge of lung measuring 7.0 x 4.0 x 3.0 cm. The surgical resection margin has been stapled shut. The pleural surface is tan-pink, smooth, glistening, and grossly unremarkable. The specimen is serially sectioned and reveals spongy, maroon-red parenchyma with no gross lesions identified. An area of hemorrhage is noted, and filled with clotted blood, which measures 1.0 x 0.5 cm. Representative sections are submitted as per block summary.

Part N specimen is received in a container labeled with the patient's name, medical record number and designated "level X lymph node." The specimen consists of multiple fragments of yellow and tan soft tissue which measure 1.4 x 1.4 x 0.7 cm in aggregate. The large fragment which appears to represent a single lymph node is bisected and

[page 4 of 5]
submitted in cassette N1 while the remainder of the specimen is submitted cassette N2.

Block Summary

A1- Level IV lymph node.
B1- Level II lymph node.
C1- Level X lymph node.
D1- Level VII lymph node.
E1-E3 Hyalinized plaque.
E4- Shaved staple resection margin nearest plaque.
E5-E6 Remaining plaque, entirely submitted.
F1- Second level VII lymph node.
G1-G2- Third level VII lymph node.
H1- Level VIII lymph node.
I1- Level IX lymph node.
J1- Second level X lymph node.
K1- Second level VIII lymph node.
L1- Representative sections of tumor.
L2- Shaved staple resection margin.
L3- Representative sections of tumor.
L4- Uninvolved lung.
M1-M3 Representative sections of lung.
M4- Shaved staple resection margin.
N1-N2- Level X lymph node.

Microscopic Description

A microscopic examination has been performed.

SP Synoptic Report

L: Thorax Lung

MACRO

SPECIMEN:

Lobe(s) of lung: Right upper, apical segment

PROCEDURE:

Wedge resection

SPECIMEN LATERALITY:

Right

TUMOR SITE:

Upper lobe

TUMOR SIZE:

Greatest dimension: 1.8 cm

TUMOR FOCALITY:

Unifocal

MICRO

HISTOLOGIC TYPE:

Squamous cell carcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

VISCERAL PLEURA INVASION:

Not identified

BRONCHIAL MARGIN:

Not applicable

VASCULAR MARGIN:

Not applicable

PARENCHYMAL MARGIN:

Uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION:

Not identified

PRIMARY TUMOR (pT):

pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral

[page 5 of 5]
pleura, without bronchoscopic evidence of
invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or
REGIONAL LYMPH NODES (pN):
pN0: No regional lymph node metastasis

Source: NCI Genomic Data Commons file 9d2ac41b-f9d5-4cb4-aa8a-202e713e8ae6 (TCGA-98-8021.76114A4D-45E7-48D6-B47C-F9952F973E1F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).